Somatic mutation profile of tumor specimen TCGA-55-8207-01A (aliquot TCGA-55-8207-01A-11D-2238-08) from TCGA case TCGA-55-8207, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.6 years (26,897 days).
Specimen TCGA-55-8207-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5118f795-497e-459d-aadb-fa184e2ff416.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8207-10A (Blood Derived Normal), aliquot TCGA-55-8207-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbf4c985-1565-421f-9dbb-89cd9a1c40e2

The open-access MAF lists 351 somatic variants for this specimen: 258 protein-altering or splice-affecting, 79 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 225, Silent 79, Nonsense Mutation 13, Intron 8, Frame Shift Ins 8, Frame Shift Del 7, Splice Site 3, RNA 3, 5'Flank 1, 3'UTR 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 34/56 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC4 | c.2968A>T p.M990L | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as COSV100972414; called by muse, mutect2, varscan2
- ACTC1 | c.635G>C p.R212P | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.499); catalogued as COSV99291753; called by muse, mutect2, varscan2
- ADAMTS2 | c.3241T>A p.S1081T | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.452); catalogued as COSV99281647; called by muse, mutect2, varscan2
- ADD1 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as rs775330429, COSV53275200; called by muse, mutect2, varscan2
- ADGRA3 | c.3236C>G p.S1079C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as COSV51568735, COSV99293145; called by muse, mutect2, varscan2
- ADGRV1 | c.5232C>G p.I1744M | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV101315724, COSV67983246; called by muse, mutect2, varscan2
- ADGRV1 | c.13477G>A p.G4493R | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1255697836, COSV67978671; called by muse, mutect2, varscan2
- AGMO | c.338C>A p.S113Y | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100693957; called by muse, mutect2, varscan2
- AGT | c.1282A>G p.I428V | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100794293; called by muse, mutect2, varscan2
- ANK2 | c.560C>T p.T187I | Missense Mutation (SNP) | VAF 105/253 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100000841; called by muse, mutect2, varscan2
- ANKAR | c.991A>G p.K331E | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV99854095; called by muse, mutect2, varscan2
- ANO3 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 59/263 reads (22%) | catalogued as COSV99881885; called by muse, mutect2, varscan2
- ATP13A1 | c.1424A>T p.Y475F | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as COSV99365980; called by muse, mutect2, varscan2
- ATP8A2 | c.1516G>A p.V506M | Missense Mutation (SNP) | VAF 78/138 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1358476114, COSV54946048; called by muse, mutect2, varscan2
- ATXN2L | c.923A>T p.Q308L | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57376215; called by muse, mutect2, varscan2
- AURKC | c.247G>T p.G83* (on ENST00000302804 / NM_001015878.2; = p.G49* on NM_003160.3) | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV100248809; called by muse, mutect2, varscan2
- B3GALT6 | c.371C>G p.A124G | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV99767409, COSV99767527; called by muse, mutect2, varscan2
- BAAT | c.92G>A p.S31N | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV99408436; called by muse, mutect2
- BICC1 | c.2753C>G p.T918S | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.306); catalogued as COSV100874812; called by muse, mutect2
- BOLA1 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV100975388; called by muse, mutect2, varscan2
- C1orf116 | c.75G>T p.M25I | Missense Mutation (SNP) | VAF 48/317 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as rs1558046270, COSV63944390; called by muse, mutect2, varscan2
- CACNA1A | c.1595C>A p.S532Y | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100801891, COSV100803376; called by muse, mutect2, varscan2
- CACNA1A | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755107633, CM115395, COSV64191409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.5218C>G p.H1740D | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100701905; called by muse, mutect2, varscan2
- CALCOCO1 | c.757A>T p.R253W | Missense Mutation (SNP) | VAF 158/273 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100017251; called by muse, mutect2, varscan2
- CAMLG | c.408A>C p.R136S | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99777718; called by muse, mutect2, varscan2
- CBLN2 | c.215C>A p.P72Q | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373648257, COSV54052134; called by muse, mutect2, varscan2
- CCDC81 | c.56C>T p.T19I | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99564197; called by muse, mutect2, varscan2
- CD226 | c.208G>T p.V70F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.223); catalogued as rs1568208686, COSV99711001; called by muse, mutect2, varscan2
- CDC20B | c.1151A>G p.H384R | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.113); catalogued as COSV99696750; called by muse, mutect2, varscan2
- CDK5 | c.746T>A p.V249E | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99876792; called by muse, mutect2, varscan2
- CEP350 | c.1018G>A p.G340S | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1028447592, COSV100658286; called by muse, mutect2, varscan2
- CHRM2 | c.1334C>A p.A445D | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV100280671, COSV100281046; called by muse, mutect2, varscan2
- CHRNA3 | c.670T>A p.C224S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs770056747, COSV100468137, COSV58776651; called by muse, mutect2, varscan2
- CMKLR1 | c.344G>T p.S115I (on ENST00000312143 / NM_001142344.2; = p.S113I on NM_004072.3) | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV100379306; called by muse, mutect2, varscan2
- CNGB3 | c.94C>A p.H32N | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100181670; called by muse, mutect2, varscan2
- CNTNAP1 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 64/363 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0.084); catalogued as COSV99226239; called by muse, mutect2, varscan2
- CNTNAP4 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770829025, COSV56692194; called by muse, mutect2, varscan2
- COASY | c.1076A>G p.Y359C | Missense Mutation (SNP) | VAF 64/355 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755259628, COSV55899224, COSV99888324; called by muse, mutect2, varscan2
- COL11A1 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 72/143 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1425451978, COSV100614954, COSV100615907; called by muse, mutect2, varscan2
- COL12A1 | c.9028A>G p.R3010G | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV100485732; called by muse, mutect2, varscan2
- COL12A1 | c.5618A>T p.Q1873L | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV100485734; called by muse, mutect2, varscan2
- CPED1 | c.893C>G p.P298R | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100120435; called by muse, mutect2, varscan2
- CR2 | c.3077T>A p.V1026D | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV100889582; called by muse, mutect2, varscan2
- CSMD1 | c.9934G>C p.G3312R (on ENST00000520002; = p.G3311R on NM_033225.6) | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100146323; called by muse, mutect2, varscan2
- CSMD3 | c.3167G>T p.W1056L (on ENST00000297405 / NM_001363185.1; = p.W952L on NM_052900.3) | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52362850; called by muse, mutect2, varscan2
- CSMD3 | c.2795C>G p.S932C (on ENST00000297405 / NM_001363185.1; = p.S828C on NM_052900.3) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as rs1235107550, COSV52183920, COSV99830628; called by muse, mutect2, varscan2
- CSMD3 | c.2534G>T p.R845L (on ENST00000297405 / NM_001363185.1; = p.R741L on NM_052900.3) | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs754786650, COSV52123877, COSV52243892; called by muse, mutect2, varscan2
- CSPG4 | c.4687G>A p.G1563S | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1414359468, COSV100413679; called by muse, mutect2, varscan2
- CTAGE15 | c.1332G>T p.L444F | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.22); catalogued as COSV101372143; called by muse, mutect2, varscan2
- CTDP1 | c.319G>T p.V107F | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs1212151939, COSV99310375; called by muse, mutect2, varscan2
- CUBN | c.8901A>T p.L2967F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV100912404; called by muse, mutect2, varscan2
- CUX2 | c.4166G>A p.C1389Y | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as COSV99919268; called by muse, mutect2, varscan2
- CYP11B1 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV99454916; called by muse, mutect2, varscan2
- CYP4V2 | c.1388G>T p.G463V | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749375330, COSV101114822; called by muse, mutect2, varscan2
- DENND3 | c.421G>T p.V141L | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV99370718; called by muse, mutect2, varscan2
- DGKB | c.953C>A p.P318Q | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.766); catalogued as COSV99338209; called by muse, mutect2, varscan2
- DGKB | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV51807066; called by muse, varscan2
- DHDDS | c.598C>G p.P200A | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV99360377; called by muse, mutect2, varscan2
- DISP3 | c.1589-2A>T p.X530_splice | Splice Site (SNP) | VAF 28/59 reads (47%) | catalogued as COSV99608119; called by muse, mutect2, varscan2
- DNMT3A | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 54/112 reads (48%) | catalogued as rs773312511, COSV53073643, COSV99261457; called by muse, mutect2, varscan2
- DOCK10 | c.3458T>G p.L1153* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99288755; called by muse, mutect2, varscan2
- DOK5 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1485675129, COSV52821292; called by muse, mutect2, varscan2
- DRD5 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV100431685; called by muse, mutect2, varscan2
- DSC2 | c.404G>T p.R135I | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51870191; called by muse, mutect2, varscan2
- DSG4 | c.1703T>A p.V568E | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100355667; called by muse, mutect2, varscan2
- DUSP3 | c.355del p.R119Gfs*16 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | catalogued as CM125590; called by mutect2, pindel
- EHD3 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100434669, COSV59029598; called by muse, mutect2, varscan2
- EPHA3 | c.2764G>T p.G922C | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1328672204, COSV60729784; called by muse, mutect2, varscan2
- EPRS1 | c.3380A>G p.Y1127C | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859351; called by muse, mutect2
- ESR2 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs543025691, COSV50831190; called by muse, mutect2, varscan2
- F9 | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 64/95 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV99496476; called by muse, mutect2, varscan2
- FAM131B | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1445554262, COSV101281784; called by muse, mutect2, varscan2
- FNIP2 | c.1732C>G p.L578V | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs760450033, COSV100032434; called by muse, mutect2, varscan2
- FZD5 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1204876089, COSV99776325; called by muse, mutect2
- GBP5 | c.1544T>A p.M515K | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV100600025; called by muse, mutect2, varscan2
- GFM2 | c.1655G>C p.G552A | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as COSV99714202; called by muse, mutect2, varscan2
- GJA1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.033); catalogued as COSV99246914; called by muse, mutect2, varscan2
- GLS | c.1393A>T p.M465L | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100289920; called by muse, mutect2, varscan2
- GPR137C | c.1069A>G p.S357G | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100397539; called by muse, mutect2, varscan2
- GPT2 | c.1435G>A p.V479M | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1372862248, COSV60840673; called by muse, mutect2
- GRID1 | c.2683C>A p.P895T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV100023246; called by muse, mutect2, varscan2
- GRIK5 | c.132G>T p.L44F | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.892); catalogued as rs369456986; called by muse, mutect2, varscan2
- HEATR1 | c.1609G>T p.A537S | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV100857588; called by muse, mutect2, varscan2
- INA | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100878603, COSV63976676; called by muse, mutect2, varscan2
- IPO9 | c.811G>C p.A271P | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100843380; called by muse, mutect2, varscan2
- IPO9 | c.2593A>T p.K865* | Nonsense Mutation (SNP) | VAF 47/187 reads (25%) | catalogued as COSV64233649; called by muse, mutect2, varscan2
- ITGA1 | c.809G>T p.R270I | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as COSV99251048; called by muse, mutect2, varscan2
- ITPR1 | c.1486G>A p.E496K (on ENST00000354582; = p.E481K on NM_002222.7) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.373); catalogued as COSV100230621; called by muse, mutect2, varscan2
- KBTBD2 | c.689A>T p.Q230L | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as COSV100406450; called by muse, mutect2, varscan2
- KCNJ4 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100341105; called by muse, mutect2, varscan2
- KCNS2 | c.1096T>C p.W366R | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99751006; called by muse, mutect2, varscan2
- KLK8 | c.573G>T p.Q191H | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.021); catalogued as COSV99143936; called by muse, mutect2, varscan2
- LCE1B | c.137T>A p.V46D | Missense Mutation (SNP) | VAF 105/389 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.183); catalogued as COSV100780269; called by muse, mutect2, varscan2
- LILRB1 | c.631C>A p.R211S (on ENST00000427581; = p.R175S on NM_006669.6) | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as COSV100207151; called by muse, mutect2, varscan2
- LMX1A | c.1000C>A p.L334I | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.021); catalogued as COSV99672013; called by muse, mutect2, varscan2
- LPA | c.4866G>C p.Q1622H | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV60312690; called by muse, mutect2, varscan2
- LRRC17 | c.368A>T p.E123V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV99978328; called by muse, mutect2
- LRRIQ3 | c.1212G>T p.M404I | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100598647, COSV63048063; called by muse, mutect2, varscan2
- LRRTM4 | c.418C>A p.L140I | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs745331273, COSV101297492; called by muse, mutect2, varscan2
- LTBP1 | c.593G>T p.G198V | Missense Mutation (SNP) | VAF 95/573 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100616821; called by muse, mutect2, varscan2
- MAGEC1 | c.1003C>A p.Q335K | Missense Mutation (SNP) | VAF 106/160 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99595375; called by muse, mutect2, varscan2
- MARCHF3 | c.461T>A p.F154Y | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100427771; called by muse, mutect2, varscan2
- MDGA2 | c.925G>C p.A309P (on ENST00000399232 / NM_001113498.2; = p.A11P on NM_182830.4) | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100636762; called by muse, mutect2, varscan2
- MECOM | c.2213G>C p.C738S (on ENST00000468789 / NM_001105078.4; = p.C926S on NM_004991.4) | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99244455; called by muse, mutect2, varscan2
- MKI67 | c.2438C>A p.A813E | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV100896388; called by muse, mutect2, varscan2
- MLLT3 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV63497128; called by muse, mutect2, varscan2
- MMAA | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99849743; called by muse, mutect2, varscan2
- MORC4 | c.2248A>G p.R750G | Missense Mutation (SNP) | VAF 103/137 reads (75%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs1452550546, COSV99717039; called by muse, mutect2, varscan2
- MPV17L2 | c.509A>T p.Y170F | Missense Mutation (SNP) | VAF 125/287 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV99717952; called by muse, mutect2, varscan2
- MUC16 | c.37262A>T p.Q12421L | Missense Mutation (SNP) | VAF 117/245 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as rs778053892, COSV67486832; called by muse, mutect2, varscan2
- MUC16 | c.26336C>T p.T8779M | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.007); catalogued as rs539402975, COSV101199296; called by muse, mutect2
- MUC17 | c.6599C>A p.S2200* | Nonsense Mutation (SNP) | VAF 292/738 reads (40%) | catalogued as COSV100072631; called by muse, mutect2, varscan2
- MYT1L | c.1556A>T p.Y519F | Missense Mutation (SNP) | VAF 95/263 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101218698, COSV101219938; called by muse, mutect2, varscan2
- NACA2 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 107/309 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV101478553; called by muse, mutect2, varscan2
- NCOA3 | c.3259G>T p.A1087S | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.078); catalogued as COSV100507397; called by muse, mutect2, varscan2
- NFRKB | c.3520A>C p.T1174P (on ENST00000446488 / NM_001143835.2; = p.T1199P on NM_006165.3) | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100451859, COSV58761064; called by muse, mutect2, varscan2
- NID1 | c.1049C>A p.T350N | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV51615039, COSV99937323; called by muse, mutect2, varscan2
- NIN | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55403477; called by muse, mutect2, varscan2
- NLRC5 | c.3361C>T p.P1121S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as COSV99346881; called by muse, mutect2
- NPAP1 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100275086; called by muse, mutect2, varscan2
- NPC1 | c.2570A>T p.D857V | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV99341112; called by muse, mutect2, varscan2
- NPC1L1 | c.1262G>T p.R421M | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56930117; called by muse, mutect2
- NPHS1 | c.3348G>T p.E1116D | Missense Mutation (SNP) | VAF 73/151 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV62290171; called by muse, varscan2
- NRXN3 | c.1765C>A p.R589S (on ENST00000335750 / NM_001330195.2; = p.R216S on NM_004796.6) | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV100200838, COSV59816102; called by muse, mutect2, varscan2
- NT5DC2 | c.481G>T p.G161W | Missense Mutation (SNP) | VAF 89/198 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100194729, COSV58740509; called by muse, mutect2, varscan2
- OR2M7 | c.508G>T p.G170W | Missense Mutation (SNP) | VAF 28/351 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370494801; called by muse, mutect2
- OR4C11 | c.776C>A p.P259H | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs565082722, COSV100155250; called by muse, mutect2, varscan2
- OR4X2 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV56582974; called by muse, mutect2, varscan2
- OR51S1 | c.374C>G p.A125G | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV100437415; called by muse, mutect2, varscan2
- OR5H2 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 82/402 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV100788693; called by muse, mutect2, varscan2
- OTOP1 | c.757A>T p.N253Y | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56393983, COSV99587544; called by muse, mutect2, varscan2
- OVCH1 | c.273C>G p.S91R | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as COSV99759297; called by muse, mutect2, varscan2
- PADI2 | c.1889C>A p.T630N | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs761292732, COSV100971874; called by muse, mutect2, varscan2
- PALD1 | c.2551G>T p.A851S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.079); catalogued as COSV99698166; called by muse, varscan2
- PARD3B | c.2268G>T p.E756D (on ENST00000406610 / NM_001302769.2; = p.E694D on NM_152526.6) | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100592967; called by muse, mutect2, varscan2
- PCDHA11 | c.1928G>A p.R643H | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); catalogued as rs543880939, COSV56529710; called by muse, mutect2, varscan2
- PCDHB13 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.009); catalogued as COSV53400807; called by muse, mutect2, varscan2
- PCDHB14 | c.68T>A p.L23* | Nonsense Mutation (SNP) | VAF 32/61 reads (52%) | catalogued as COSV99505736; called by muse, mutect2, varscan2
- PCDHB14 | c.69G>T p.L23F | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); catalogued as COSV53391503; called by muse, mutect2, varscan2
- PCDHB3 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as COSV99164812; called by muse, mutect2, varscan2
- PCDHGA2 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99535125; called by muse, mutect2, varscan2
- PDZRN4 | c.1616C>A p.T539K (on ENST00000402685 / NM_001164595.2; = p.T281K on NM_013377.4) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs776524642, COSV100114147; called by muse, varscan2
- PEG3 | c.3331G>T p.D1111Y | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99688317; called by muse, mutect2, varscan2
- PKHD1L1 | c.5872A>T p.T1958S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.129); catalogued as COSV101005900; called by muse, mutect2, varscan2
- PLEKHH2 | c.887G>C p.G296A | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV99174579; called by muse, mutect2
- POLR2A | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as COSV100495643; called by muse, mutect2, varscan2
- POTEE | c.835G>T p.G279C | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.657); catalogued as COSV100387524, COSV100388885; called by muse, mutect2, varscan2
- PPIP5K2 | c.3182C>T p.A1061V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.217); catalogued as rs782150216, COSV100383523; called by muse, mutect2, varscan2
- PPP1R3A | c.2282G>T p.R761L | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99492473; called by muse, varscan2
- PRG4 | c.1376C>A p.P459H | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV100798163; called by muse, mutect2, varscan2
- PRKCB | c.1279G>C p.D427H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100333233, COSV57764210; called by muse, mutect2, varscan2
- PRKCE | c.2006A>G p.K669R | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100077426; called by muse, mutect2, varscan2
- PROKR1 | c.436G>T p.V146F | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs866673060, COSV100375416; called by muse, mutect2, varscan2
- PRR30 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.046); catalogued as rs562865918, COSV53207412, COSV99574418; called by muse, mutect2, varscan2
- PRR5L | c.444G>C p.Q148H | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV100286966; called by muse, mutect2, varscan2
- PRSS1 | c.481C>A p.L161M | Missense Mutation (SNP) | VAF 137/362 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1444451561, COSV100297900; called by muse, mutect2, varscan2
- RAB11FIP2 | c.263A>T p.H88L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100843029; called by muse, mutect2, varscan2
- RAB11FIP5 | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99241885; called by muse, mutect2, varscan2
- RAG2 | c.721C>A p.P241T | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100271208, COSV57557541; called by muse, mutect2, varscan2
- RANBP2 | c.4732G>A p.V1578I | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs775467593, COSV99311774; called by muse, mutect2, varscan2
- RAPGEF6 | c.3032C>T p.P1011L | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99726035; called by muse, mutect2, varscan2
- RESF1 | c.3463G>T p.G1155* | Nonsense Mutation (SNP) | VAF 80/144 reads (56%) | catalogued as COSV100440257; called by muse, mutect2, varscan2
- ROBO2 | c.3421C>A p.P1141T | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.344); catalogued as COSV100165677, COSV59931769; called by muse, mutect2, varscan2
- ROPN1L | c.406A>T p.M136L | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as COSV99928590; called by muse, mutect2, varscan2
- RORB | c.1204G>C p.A402P (on ENST00000396204 / NM_001365023.1; = p.A391P on NM_006914.4) | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100974265, COSV65338558; called by muse, mutect2, varscan2
- RSPH14 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.089); catalogued as COSV99320606; called by muse, mutect2, varscan2
- RYR2 | c.6955G>A p.V2319I | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100769321; called by muse, mutect2, varscan2
- RYR3 | c.14160C>A p.Y4720* (on ENST00000389232; = p.Y4721* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 31/55 reads (56%) | catalogued as COSV101212435; called by muse, mutect2, varscan2
- S100A16 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 74/139 reads (53%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.956); catalogued as COSV100905884, COSV100905904; called by muse, mutect2, varscan2
- S100A7L2 | c.11C>A p.P4H | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV100906869, COSV64194894; called by muse, mutect2, varscan2
- SAMD14 | c.271G>T p.G91W | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV99557403; called by muse, mutect2, varscan2
- SASH1 | c.1092G>T p.K364N | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV100821105; called by muse, mutect2, varscan2
- SDAD1 | c.1411G>T p.D471Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100668584; called by muse, mutect2, varscan2
- SEMA4B | c.1826T>C p.L609S | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1262981588, COSV100153272; called by muse, mutect2, varscan2
- SEMA6B | c.1134C>A p.C378* | Nonsense Mutation (SNP) | VAF 20/87 reads (23%) | catalogued as COSV100014764; called by muse, mutect2, varscan2
- SFRP2 | c.815C>A p.S272* | Nonsense Mutation (SNP) | VAF 39/117 reads (33%) | catalogued as COSV99923217, COSV99923251; called by muse, mutect2, varscan2
- SFRP2 | c.814T>C p.S272P | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.926); catalogued as COSV99923254; called by muse, mutect2, varscan2
- SHOX | c.215A>T p.K72M | Missense Mutation (SNP) | VAF 65/101 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); catalogued as COSV100478959; called by muse, mutect2, varscan2
- SLC12A2 | c.2578G>A p.A860T | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.656); catalogued as COSV99320893; called by muse, mutect2, varscan2
- SLC14A2 | c.1127-1G>T p.X376_splice | Splice Site (SNP) | VAF 54/93 reads (58%) | catalogued as COSV99675327; called by muse, mutect2, varscan2
- SLC45A4 | c.1406G>T p.R469L (on ENST00000517878 / NM_001286646.2; = p.R418L on NM_001080431.2) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.825); catalogued as COSV99196796; called by muse, mutect2, varscan2
- SLC6A15 | c.2099G>C p.G700A | Missense Mutation (SNP) | VAF 130/194 reads (67%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.206); catalogued as COSV99880526; called by muse, mutect2, varscan2
- SNCB | c.142G>T p.V48L | Missense Mutation (SNP) | VAF 98/188 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV100031211; called by muse, mutect2, varscan2
- SNTG1 | c.1213C>A p.L405I | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99382850; called by muse, mutect2, varscan2
- SPCS2 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 84/227 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99734360; called by muse, mutect2, varscan2
- SUPT6H | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.543); catalogued as COSV100112261; called by muse, mutect2, varscan2
- SYT6 | c.1136C>A p.T379N (on ENST00000610222 / NM_001366225.1; = p.T294N on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101059630; called by muse, mutect2, varscan2
- SYTL2 | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100314001; called by muse, mutect2, varscan2
- TAAR6 | c.635T>C p.I212T | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV99256585; called by muse, mutect2, varscan2
- TACC2 | c.8231A>T p.Q2744L (on ENST00000334433; = p.Q822L on NM_006997.4) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV99586789, COSV99586875; called by muse, mutect2, varscan2
- TARS1 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99465763; called by muse, mutect2, varscan2
- TAS1R2 | c.1613G>A p.C538Y | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100946189; called by muse, mutect2, varscan2
- TBC1D9 | c.3518A>T p.H1173L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV101464312; called by muse, varscan2
- TCEA1 | c.9C>A p.D3E | Missense Mutation (SNP) | VAF 71/198 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101124262; called by muse, mutect2, varscan2
- TDRD1 | c.981G>A p.Q327= | Splice Region (SNP) | VAF 18/64 reads (28%) | catalogued as COSV99314378; called by muse, mutect2, varscan2
- TDRD6 | c.3422T>C p.L1141P | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100287416; called by muse, mutect2, varscan2
- TENM2 | c.7016C>G p.S2339C (on ENST00000518659 / NM_001122679.2; = p.S2100C on NM_001080428.3) | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101318434; called by muse, mutect2, varscan2
- TENM2 | c.7774G>A p.D2592N (on ENST00000518659 / NM_001122679.2; = p.D2353N on NM_001080428.3) | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV101318435; called by muse, mutect2
- THBS3 | c.664T>A p.S222T | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.054); catalogued as COSV100857559; called by muse, mutect2, varscan2
- TLK1 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); catalogued as COSV100687929; called by muse, mutect2, varscan2
- TLR6 | c.299A>T p.Q100L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV101126258; called by muse, mutect2, varscan2
- TMEM132A | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99134647; called by muse, mutect2, varscan2
- TMEM143 | c.1304G>A p.G435D | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.255); catalogued as COSV99507139; called by muse, mutect2, varscan2
- TMEM223 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as rs771984852, COSV99585075; called by muse, mutect2, varscan2
- TRIM11 | c.790G>T p.V264F | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99488251; called by muse, mutect2
- TRIM54 | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs750346891, COSV99940870; called by muse, mutect2, varscan2
- TRIM58 | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 108/479 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63572328; called by muse, mutect2, varscan2
- TRPS1 | c.2941G>T p.E981* (on ENST00000220888 / NM_001330599.2; = p.E994* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 97/238 reads (41%) | catalogued as COSV99629728; called by muse, mutect2, varscan2
- TSHZ3 | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.117); catalogued as COSV99550738, COSV99551172; called by muse, mutect2, varscan2
- UBE2V2 | c.190A>T p.S64C | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV101568630; called by muse, mutect2, varscan2
- UBR7 | c.885G>C p.Q295H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99184215; called by muse, mutect2, varscan2
- UGT3A1 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99954591; called by muse, mutect2, varscan2
- UNC79 | c.1250G>T p.G417V (on ENST00000393151 / NM_001346218.2; = p.G240V on NM_020818.5) | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99827010; called by muse, mutect2, varscan2
- VAV3 | c.1505C>A p.S502Y | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750852069, COSV100579529; called by muse, mutect2, varscan2
- VCAN | c.9401A>T p.N3134I | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99425324; called by muse, mutect2, varscan2
- VWA3A | c.2452A>T p.T818S | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV100240778; called by muse, mutect2, varscan2
- YIPF4 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.768); catalogued as COSV99479807; called by muse, mutect2, varscan2
- ZBED9 | c.3414G>T p.Q1138H | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.205); catalogued as COSV101509195; called by muse, mutect2, varscan2
- ZBP1 | c.1244T>C p.V415A | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs764079652, COSV100473297; called by muse, mutect2, varscan2
- ZBTB46 | c.1052C>A p.P351H | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99829000; called by muse, mutect2, varscan2
- ZCCHC13 | c.376G>T p.A126S | Missense Mutation (SNP) | VAF 50/64 reads (78%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as COSV100272496, COSV59866426; called by muse, mutect2, varscan2
- ZDHHC8 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as rs373907365; called by muse, mutect2, varscan2
- ZFPM2 | c.2213G>T p.R738L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780534224, COSV101023145, COSV65874081; called by muse, mutect2
- ZFPM2 | c.2335G>A p.G779R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as rs376994109; called by muse, mutect2, varscan2
- ZNF25 | c.242A>G p.D81G | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV56924310; called by muse, mutect2, varscan2
- ZNF257 | c.1586A>G p.Y529C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV101448080; called by muse, mutect2, varscan2
- ZNF382 | c.491G>T p.S164I | Missense Mutation (SNP) | VAF 102/253 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.28); catalogued as COSV99497680; called by muse, mutect2, varscan2
- ZNF521 | c.628G>T p.G210W | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100831824; called by muse, mutect2, varscan2
- ZNF597 | c.14C>A p.P5H | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100071950; called by muse, mutect2, varscan2
- ZNF835 | c.736G>A p.G246S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs763139627, COSV73379258; called by muse, mutect2, varscan2
- ZNF875 | c.1289G>A p.R430K | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as COSV100183210; called by muse, mutect2
- CRB1 | c.3551dup p.N1184Kfs*10 | Frame Shift Ins (INS) | VAF 47/95 reads (49%) | called by mutect2, pindel, varscan2
- DCDC1 | c.3242del p.K1081Sfs*8 (on ENST00000597505 / NM_001367979.1; = p.K188Sfs*8 on NM_020869.3) | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- GAD2 | c.1745del p.G582Dfs*16 | Frame Shift Del (DEL) | VAF 25/103 reads (24%) | called by mutect2, pindel, varscan2
- GAGE1 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- GRIN2D | c.1432del p.R478Afs*15 | Frame Shift Del (DEL) | VAF 41/145 reads (28%) | called by mutect2, pindel, varscan2
- HLA-C | c.790del p.T264Pfs*33 | Frame Shift Del (DEL) | VAF 20/118 reads (17%) | called by mutect2, pindel, varscan2
- HOXD3 | c.227dup p.R77Efs*9 | Frame Shift Ins (INS) | VAF 20/114 reads (18%) | called by mutect2, pindel, varscan2
- IGKV1D-42 | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- IGKV3D-15 | c.314T>G p.V105G | Missense Mutation (SNP) | VAF 79/102 reads (77%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- KDM5C | c.1801dup p.Y601Lfs*21 | Frame Shift Ins (INS) | VAF 37/70 reads (53%) | called by mutect2, pindel, varscan2
- KIR2DL4 | c.505G>T p.A169S (on ENST00000396284; = p.A130S on NM_001080770.2) | Missense Mutation (SNP) | VAF 88/253 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LAMA5 | c.9595_9606del p.G3199_H3202del | In Frame Del (DEL) | VAF 20/189 reads (11%) | called by mutect2, pindel
- LRP1B | c.13224dup p.E4409Rfs*19 | Frame Shift Ins (INS) | VAF 44/182 reads (24%) | called by pindel, varscan2
- LRP1B | c.13219G>C p.D4407H | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, varscan2
- MUC5AC | c.13997G>T p.R4666L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.21); called by muse, mutect2, varscan2
- N4BP1 | c.378dup p.V127Cfs*5 | Frame Shift Ins (INS) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- NBPF11 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 70/416 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- OR4D9 | c.190dup p.R64Pfs*7 | Frame Shift Ins (INS) | VAF 128/365 reads (35%) | called by mutect2, pindel, varscan2
- PRKCB | c.942del p.K315Rfs*23 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- SFTPB | c.364dup p.L122Pfs*11 | Frame Shift Ins (INS) | VAF 40/192 reads (21%) | called by mutect2, pindel, varscan2
- SPANXB1 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 44/527 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.998); called by muse, mutect2
- SRGAP1 | c.257_263+6delinsTT p.X86_splice | Splice Site (DEL) | VAF 41/71 reads (58%) | called by pindel, varscan2*
- TENM2 | c.1572del p.R525Gfs*46 (on ENST00000518659 / NM_001122679.2; = p.R293Gfs*46 on NM_001080428.3) | Frame Shift Del (DEL) | VAF 44/223 reads (20%) | called by mutect2, pindel, varscan2
- TRAV19 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF804B | c.2010dup p.K671Efs*10 | Frame Shift Ins (INS) | VAF 18/113 reads (16%) | called by mutect2, pindel, varscan2
- ABCA3 | c.1383G>A p.V461= | Silent (SNP) | VAF 53/510 reads (10%) | catalogued as rs778566772, CD068738, COSV57062388; called by muse, mutect2
- ADAM29 | c.1953C>A p.P651= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as COSV100821965; called by muse, mutect2, varscan2
- ADAMTS3 | c.1509A>G p.K503= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as COSV99710702; called by muse, mutect2, varscan2
- ADGRA1 | c.303A>T p.I101= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV101192678; called by muse, mutect2, varscan2
- ALPI | c.462G>T p.R154= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV99785808; called by muse, mutect2, varscan2
- ANGPTL7 | c.579G>A p.Q193= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV100815934; called by muse, mutect2, varscan2
- BCL11B | c.204G>T p.G68= | Silent (SNP) | VAF 49/113 reads (43%) | catalogued as COSV100595387; called by muse, mutect2, varscan2
- BSN | c.4800G>T p.P1600= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs374334932, COSV99607943; called by muse, mutect2, varscan2
- CACNA1C | c.180G>T p.R60= | Silent (SNP) | VAF 6/8 reads (75%) | called by mutect2, varscan2
- CACNA1D | c.1020G>C p.P340= | Silent (SNP) | VAF 71/346 reads (21%) | catalogued as COSV55450811; called by muse, mutect2, varscan2
- CDK5RAP1 | c.51A>T p.G17= | Silent (SNP) | VAF 80/219 reads (37%) | catalogued as COSV100212009; called by muse, mutect2, varscan2
- CELA2A | c.750C>A p.S250= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as COSV100657524, COSV62747524; called by muse, mutect2, varscan2
- CETP | c.63C>A p.G21= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as COSV99569971; called by muse, mutect2, varscan2
- CHRNA1 | c.30T>C p.F10= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV99650318; called by muse, mutect2, varscan2
- CLCN1 | c.2649C>A p.P883= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV100577927; called by muse, mutect2, varscan2
- CLEC5A | c.495C>T p.G165= | Silent (SNP) | VAF 34/163 reads (21%) | catalogued as COSV101407759; called by muse, mutect2, varscan2
- COL17A1 | c.2580C>G p.G860= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100793117; called by muse, mutect2, varscan2
- COL5A3 | c.2937C>A p.P979= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV99318511; called by muse, mutect2, varscan2
- COL5A3 | c.2118G>T p.P706= | Silent (SNP) | VAF 47/116 reads (41%) | catalogued as COSV53410785; called by muse, mutect2, varscan2
- CPS1 | c.1269C>G p.S423= | Silent (SNP) | VAF 66/204 reads (32%) | catalogued as COSV99242652; called by muse, mutect2, varscan2
- CR2 | c.3078T>A p.V1026= | Silent (SNP) | VAF 64/145 reads (44%) | catalogued as COSV100889583; called by muse, mutect2, varscan2
- CSPG4 | c.1806C>A p.P602= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100413680, COSV100413771; called by muse, mutect2, varscan2
- DDIAS | c.1884C>T p.C628= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs1437686081, COSV100231125; called by muse, mutect2, varscan2
- DNAH7 | c.3687C>T p.S1229= | Silent (SNP) | VAF 71/184 reads (39%) | catalogued as COSV100414634; called by muse, mutect2, varscan2
- ERC2 | c.120A>T p.T40= | Silent (SNP) | VAF 47/133 reads (35%) | catalogued as COSV99883125; called by muse, mutect2, varscan2
- FFAR2 | c.540G>T p.R180= | Silent (SNP) | VAF 63/146 reads (43%) | catalogued as COSV99876027; called by muse, mutect2, varscan2
- FGFR2 | c.2001C>T p.V667= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100335951; called by muse, mutect2, varscan2
- GCKR | c.447G>A p.R149= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as rs766995710, COSV99253855; called by muse, mutect2, varscan2
- GRIN3A | c.429C>T p.P143= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV100701445, COSV100701460; called by muse, mutect2, varscan2
- HGD | c.57T>G p.P19= | Silent (SNP) | VAF 68/185 reads (37%) | catalogued as rs1268206045, COSV52200436, COSV99380834, COSV99381063; called by muse, mutect2, varscan2
- HRNR | c.2730G>A p.G910= | Silent (SNP) | VAF 99/348 reads (28%) | catalogued as rs764516678, COSV100913271, COSV64262031; called by muse, mutect2, varscan2
- IGKV3D-15 | c.30C>A p.L10= | Silent (SNP) | VAF 4/33 reads (12%) | called by mutect2, varscan2
- IGSF3 | c.819C>T p.N273= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as rs147777098; called by muse, mutect2, varscan2
- INAVA | c.1938G>T p.G646= | Silent (SNP) | VAF 26/153 reads (17%) | catalogued as COSV100949944; called by muse, mutect2, varscan2
- ITGA8 | c.2223C>A p.G741= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV65226825; called by muse, mutect2
- KCNC1 | c.939C>A p.V313= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV56391866, COSV99789055; called by muse, mutect2, varscan2
- KIF1A | c.306C>A p.G102= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100240461; called by muse, mutect2, varscan2
- KRT37 | c.762G>T p.G254= | Silent (SNP) | VAF 144/493 reads (29%) | catalogued as COSV99845384; called by muse, mutect2, varscan2
- LDHAL6B | c.129C>A p.L43= | Silent (SNP) | VAF 41/60 reads (68%) | catalogued as COSV99895110; called by muse, mutect2, varscan2
- LPO | c.1479C>T p.L493= | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as COSV99228635; called by muse, mutect2, varscan2
- LTF | c.1038C>A p.A346= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV99207533; called by muse, mutect2, varscan2
- MLEC | c.267G>A p.L89= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99949615; called by muse, mutect2, varscan2
- MRC1 | c.3897G>A p.L1299= | Silent (SNP) | VAF 160/381 reads (42%) | called by muse, mutect2, varscan2
- MYOF | c.1407G>T p.G469= | Silent (SNP) | VAF 32/151 reads (21%) | catalogued as COSV100825552; called by muse, mutect2, varscan2
- NEUROD1 | c.48C>A p.P16= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as rs188971339; called by muse, mutect2, varscan2
- NPY5R | c.1090C>A p.R364= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV100642721, COSV58451863, COSV58452915; called by muse, mutect2, varscan2
- OR4C15 | c.258C>A p.V86= (on ENST00000314644; = p.V32= on NM_001001920.2) | Silent (SNP) | VAF 83/188 reads (44%) | catalogued as COSV100115552, COSV58951703; called by muse, mutect2, varscan2
- OR7E24 | c.99G>T p.L33= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV101509649; called by muse, mutect2, varscan2
- OR9G1 | c.420T>C p.C140= | Silent (SNP) | VAF 44/212 reads (21%) | catalogued as COSV100380336; called by muse, mutect2, varscan2
- P2RX6 | c.600C>A p.I200= | Silent (SNP) | VAF 46/86 reads (53%) | catalogued as COSV100298634; called by muse, mutect2, varscan2
- PAK3 | c.213T>C p.S71= | Silent (SNP) | VAF 141/191 reads (74%) | catalogued as COSV99456985; called by muse, mutect2, varscan2
- PCDH7 | c.1752C>A p.I584= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV100687968; called by muse, mutect2, varscan2
- PCDHB12 | c.1710G>A p.A570= | Silent (SNP) | VAF 45/219 reads (21%) | catalogued as COSV99507090; called by muse, mutect2, varscan2
- PCDHGA12 | c.639G>T p.T213= | Silent (SNP) | VAF 47/157 reads (30%) | catalogued as COSV99339274; called by muse, mutect2, varscan2
- PCLO | c.4296A>T p.S1432= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV61639736; called by muse, mutect2, varscan2
- PLCB4 | c.3199C>T p.L1067= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV99595009; called by muse, mutect2, varscan2
- PNKP | c.1434C>G p.V478= | Silent (SNP) | VAF 59/237 reads (25%) | catalogued as COSV99681661; called by muse, mutect2, varscan2
- POTEF | c.1149A>G p.S383= | Silent (SNP) | VAF 36/149 reads (24%) | catalogued as COSV100664748; called by muse, mutect2, varscan2
- POU1F1 | c.225C>A p.T75= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV100622626; called by muse, mutect2, varscan2
- POU4F2 | c.105C>A p.G35= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99850456; called by muse, mutect2, varscan2
- PPT1 | c.837A>T p.L279= (on ENST00000433473; = p.L280= on NM_000310.4) | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV100472162; called by muse, mutect2, varscan2
- PROKR1 | c.435T>C p.T145= | Silent (SNP) | VAF 56/173 reads (32%) | catalogued as rs1253824785, COSV100375412; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1839C>A p.I613= | Silent (SNP) | VAF 92/249 reads (37%) | catalogued as COSV99228828; called by muse, mutect2, varscan2
- RPS3 | c.534A>G p.R178= | Silent (SNP) | VAF 34/58 reads (59%) | catalogued as rs1407557641, COSV99584327; called by muse, mutect2, varscan2
- SEC24B | c.936A>T p.P312= | Silent (SNP) | VAF 53/161 reads (33%) | catalogued as COSV99493223; called by muse, mutect2, varscan2
- SLC22A7 | c.1353G>A p.L451= (on ENST00000372585 / NM_153320.2; = p.L449= on NM_006672.3) | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs745719776, COSV99240250; called by muse, mutect2, varscan2
- SLC35A5 | c.1143G>A p.P381= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs760572824, COSV53725982; called by muse, mutect2, varscan2
- SPHKAP | c.2880T>C p.C960= | Silent (SNP) | VAF 24/170 reads (14%) | catalogued as COSV100763978; called by muse, mutect2, varscan2
- SPOPL | c.756A>G p.K252= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as rs151051467, COSV99699408; called by muse, mutect2, varscan2
- SYNDIG1 | c.267C>A p.P89= | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as COSV100965228; called by muse, mutect2, varscan2
- TAS2R38 | c.618C>T p.F206= | Silent (SNP) | VAF 16/113 reads (14%) | catalogued as COSV71886122; called by muse, mutect2, varscan2
- TBX20 | c.294C>A p.A98= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV101282363; called by muse, mutect2, varscan2
- TRAV19 | c.315G>C p.V105= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- UNC80 | c.810G>A p.V270= | Silent (SNP) | VAF 60/174 reads (34%) | catalogued as COSV99779101; called by muse, mutect2, varscan2
- VWCE | c.1704C>T p.C568= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100075737; called by muse, mutect2, varscan2
- XKR4 | c.1506C>A p.G502= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as rs765354178, COSV100531898, COSV59326324; called by muse, mutect2, varscan2
- ZIC1 | c.948C>G p.S316= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV51559482, COSV99291449, COSV99291765; called by muse, mutect2, varscan2
- ZNF142 | c.3151C>T p.L1051= (on ENST00000411696 / NM_001379660.1; = p.L851= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as COSV101376916; called by muse, mutect2, varscan2
- ZNF292 | c.4800C>T p.T1600= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV100369554, COSV100370165; called by muse, mutect2, varscan2
- ABCB5 | c.1707+393A>T | Intron (SNP) | VAF 96/242 reads (40%) | catalogued as COSV99327990; called by muse, mutect2, varscan2
- AL590867.2 | n.428C>G | RNA (SNP) | VAF 27/47 reads (57%) | catalogued as rs377517241; called by muse, mutect2, varscan2
- ARIH2 | chr3:48918403 G>A | 5'Flank (SNP) | VAF 54/132 reads (41%) | catalogued as COSV100711269; called by muse, mutect2, varscan2
- CNGA2 | c.-2G>T | 5'UTR (SNP) | VAF 94/132 reads (71%) | catalogued as COSV100323558; called by muse, mutect2, varscan2
- CPLANE1 | c.*3217G>T | 3'UTR (SNP) | VAF 71/210 reads (34%) | catalogued as COSV99950180; called by muse, mutect2, varscan2
- DIO2 | c.223-2436T>A | Intron (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- DST | c.4297-4317G>C | Intron (SNP) | VAF 93/290 reads (32%) | catalogued as COSV99753944; called by muse, mutect2, varscan2
- EI24P4 | n.924C>A | RNA (SNP) | VAF 79/371 reads (21%) | called by muse, mutect2, varscan2
- MOXD1 | c.264+8937C>A | Intron (SNP) | VAF 6/9 reads (67%) | catalogued as COSV100914265; called by muse, mutect2, varscan2
- NBPF11 | c.-548-3178G>T | Intron (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-1990G>T | Intron (SNP) | VAF 3/39 reads (8%) | catalogued as COSV100389734; called by muse, mutect2
- RBM44 | c.-98-1989G>T | Intron (SNP) | VAF 3/40 reads (8%) | catalogued as rs1159008920, COSV100389735; called by muse, mutect2
- SPATA8 | n.814C>A | RNA (SNP) | VAF 28/64 reads (44%) | catalogued as COSV100138926; called by muse, mutect2, varscan2
- TTN | c.10360+4924G>T | Intron (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100604304; called by muse, mutect2, varscan2
